Somatic mutation profile of tumor specimen 0DGOAT from CCDI case PBBTNU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 16.6 years (6,074 days).
Specimen 0DGOAT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30736f97-7ba3-4b2f-ae6e-0fa07c77d5a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGOBB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b5205bb-dece-478b-b7f8-2fe17a8c7d30

The open-access MAF lists 33 somatic variants for this specimen: 15 protein-altering or splice-affecting, 13 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 13, 3'UTR 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HMCN1 | c.8221G>A p.G2741R | Missense Mutation (SNP) | VAF 241/548 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149435109; called by muse, mutect2, varscan2
- INPPL1 | c.3313C>T p.P1105S | Missense Mutation (SNP) | VAF 358/620 reads (58%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1441314714; called by muse, varscan2
- KLK12 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 234/848 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs563322085; called by muse, varscan2
- RP1 | c.3593A>T p.E1198V | Missense Mutation (SNP) | VAF 272/1368 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.676); catalogued as COSV99606345; called by muse, mutect2, varscan2
- SERPINB1 | c.1130C>A p.S377Y | Missense Mutation (SNP) | VAF 116/491 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV66313906; called by mutect2, varscan2
- ASXL3 | c.2893A>G p.K965E | Missense Mutation (SNP) | VAF 115/482 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- ATRNL1 | c.2473G>A p.D825N | Missense Mutation (SNP) | VAF 140/434 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); called by muse, varscan2
- IQUB | c.1397C>A p.A466D | Missense Mutation (SNP) | VAF 82/565 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.102); called by mutect2, varscan2
- N4BP3 | c.658G>A p.G220S | Missense Mutation (SNP) | VAF 119/506 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- NAALADL2 | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 285/505 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- PARP4 | c.1049G>T p.C350F | Missense Mutation (SNP) | VAF 84/310 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PCLO | c.11410G>A p.G3804R | Missense Mutation (SNP) | VAF 153/953 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKHD1L1 | c.143G>T p.R48M | Missense Mutation (SNP) | VAF 224/647 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- SLC5A7 | c.1739A>G p.Q580R | Missense Mutation (SNP) | VAF 94/402 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- TES | c.289C>G p.P97A | Missense Mutation (SNP) | VAF 130/1113 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- ACSL5 | c.1290C>T p.F430= (on ENST00000354273; = p.F486= on NM_016234.3) | Silent (SNP) | VAF 134/457 reads (29%) | called by muse, mutect2, varscan2
- C13orf42 | c.240G>A p.S80= | Silent (SNP) | VAF 178/629 reads (28%) | catalogued as rs956124629; called by muse, mutect2, varscan2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 11/314 reads (4%) | catalogued as rs1167537044; called by muse, mutect2
- CPNE4 | c.192T>A p.T64= | Silent (SNP) | VAF 131/406 reads (32%) | called by muse, mutect2, varscan2
- LRFN1 | c.1977C>T p.S659= | Silent (SNP) | VAF 82/645 reads (13%) | catalogued as rs1341761385; called by muse, mutect2, varscan2
- MEI1 | c.1959T>C p.S653= | Silent (SNP) | VAF 394/640 reads (62%) | catalogued as rs771345122; called by muse, varscan2
- MEPCE | c.1365C>T p.G455= | Silent (SNP) | VAF 193/1338 reads (14%) | catalogued as rs1362441433, COSV52769025, COSV99439822; called by muse, mutect2, varscan2
- MOCS2 | c.351A>G p.K117= | Silent (SNP) | VAF 125/596 reads (21%) | catalogued as rs908604588; called by muse, mutect2, varscan2
- SLC4A5 | c.243C>T p.D81= | Silent (SNP) | VAF 138/703 reads (20%) | called by muse, mutect2, varscan2
- TEX15 | c.4791C>T p.Y1597= (on ENST00000256246; = p.Y1980= on NM_001350162.2) | Silent (SNP) | VAF 184/985 reads (19%) | catalogued as rs201220558, COSV56353879; called by muse, mutect2, varscan2
- ULBP3 | c.234A>G p.L78= | Silent (SNP) | VAF 204/594 reads (34%) | called by muse, varscan2
- WASHC4 | c.670C>T p.L224= | Silent (SNP) | VAF 52/236 reads (22%) | called by muse, varscan2
- ZNF385D | c.1155C>A p.T385= | Silent (SNP) | VAF 89/436 reads (20%) | catalogued as rs200768881, COSV99874992; called by muse, mutect2, varscan2
- LILRA2 | c.*12G>A | 3'UTR (SNP) | VAF 226/1233 reads (18%) | called by muse, mutect2, varscan2
- LIMS2 | c.660+94C>A | Intron (SNP) | VAF 80/269 reads (30%) | called by muse, mutect2, varscan2
- PRKCQ | c.*40C>T | 3'UTR (SNP) | VAF 94/337 reads (28%) | catalogued as COSV99578163; called by muse, mutect2, varscan2
- SIRT5 | c.*69T>C | 3'UTR (SNP) | VAF 38/123 reads (31%) | called by muse, mutect2, varscan2
- UNC5D | c.*86G>A | 3'UTR (SNP) | VAF 73/211 reads (35%) | catalogued as rs906904625, COSV99773623; called by muse, mutect2, varscan2
